Somatic mutation profile of tumor specimen TCGA-ZG-A9LY-01A (aliquot TCGA-ZG-A9LY-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9LY, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.1 years (21,942 days).
Specimen TCGA-ZG-A9LY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9a61cae-6bb9-4ee9-bf42-1a48828886f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9LY-10A (Blood Derived Normal), aliquot TCGA-ZG-A9LY-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab95f4e0-024d-4f25-b0cd-d47fc2e279e3

The open-access MAF lists 32 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 21, Silent 6, Nonsense Mutation 2, Translation Start Site 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.65T>G p.L22R | Missense Mutation (SNP) | VAF 21/113 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV69042031, COSV69042523, COSV69043220; called by muse, mutect2, varscan2
- AC242842.3 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 3/239 reads (1%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1185110962; called by muse, mutect2
- ALK | c.826T>G p.Y276D | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as COSV101202039; called by muse, mutect2, varscan2
- B9D1 | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1417423091, COSV99264952; called by muse, mutect2, varscan2
- DENND2C | c.2147A>G p.Y716C (on ENST00000393274 / NM_001256404.2; = p.Y659C on NM_198459.4) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781305601, COSV101283932; called by muse, mutect2, varscan2
- FN1 | c.5263C>T p.R1755W | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs982522475, COSV100117153; called by muse, mutect2, varscan2
- JADE3 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs782032391, COSV99509898, COSV99510098; called by muse, mutect2, varscan2
- KRT4 | c.917G>T p.S306I | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV99542950; called by muse, mutect2, varscan2
- LIG4 | c.1589A>G p.H530R | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs766018641, COSV100799913; called by muse, mutect2, varscan2
- MFN2 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99336776; called by muse, mutect2, varscan2
- MYCT1 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 10/77 reads (13%) | catalogued as rs751903305, COSV65891190; called by muse, mutect2, varscan2
- NELL2 | c.270G>T p.L90F | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV100419721; called by muse, mutect2, varscan2
- NGEF | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1300856901, COSV50914726, COSV50943982; called by muse, mutect2, varscan2
- NLRP7 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs775497218, COSV100052686; called by muse, mutect2, varscan2
- NR2C1 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1329285061, COSV58011893; called by muse, mutect2
- NUP214 | c.2479G>A p.D827N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845297, COSV63913226; called by muse, mutect2, varscan2
- P2RY14 | c.888C>A p.F296L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.931); catalogued as rs754128917, COSV56396535; called by muse, mutect2, varscan2
- PCDHA9 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.031); catalogued as rs1317761194, COSV99061392; called by muse, mutect2, varscan2
- PCDHAC1 | c.2341C>T p.R781* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as rs782744711, COSV53858986; called by muse, mutect2, varscan2
- PNLIP | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.136); catalogued as rs140844816; called by muse, mutect2, varscan2
- POM121C | c.1082A>G p.H361R (on ENST00000607367; = p.H119R on NM_001099415.3) | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.796); catalogued as COSV99992733; called by muse, mutect2, varscan2
- RO60 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.456); catalogued as COSV100814384, COSV66475205; called by muse, mutect2, varscan2
- SLC6A14 | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV100903132; called by muse, mutect2, varscan2
- TM9SF4 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1402853685, COSV54107188; called by muse, mutect2, varscan2
- BRPF1 | c.1570del p.I524Sfs*5 | Frame Shift Del (DEL) | VAF 13/69 reads (19%) | called by mutect2, pindel, varscan2
- TCHP | c.1321-7_1322del p.X441_splice | Splice Site (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- CACNA1A | c.2001C>T p.G667= | Silent (SNP) | VAF 21/117 reads (18%) | catalogued as rs373695561; called by muse, mutect2, varscan2
- GOLGB1 | c.9735A>G p.L3245= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100100675; called by muse, mutect2, varscan2
- HADHB | c.249G>A p.A83= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as rs1304689890, COSV58547165; called by muse, mutect2, varscan2
- KRT4 | c.918C>T p.S306= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99542944; called by muse, mutect2, varscan2
- SHROOM2 | c.3318G>T p.V1106= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV101098651; called by muse, mutect2, varscan2
- TMEM145 | c.966G>A p.L322= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV100003667; called by muse, mutect2
